TCGA case TCGA-CU-A0YR — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/811b3950-36e7-485f-bc48-aca1eee2ddef

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 83 years; Vital status: Dead; Days to death: 460 days (1.3 years).

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 84.0 years (30,674 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 4; Lymph nodes tested: 11; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T3b.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary; Age at diagnosis: 84.1 years (30,708 days); Days to diagnosis: 34 days; AJCC staging edition: 7th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 34 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 84.6 years (30,893 days); Days to diagnosis: 219 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 84.6 years (30,904 days); Days to diagnosis: 230 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 219 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 219 days.
- Day 230 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 460 days (1.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75.4 kg; Height: 177.8 cm; BMI: 23.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 12; Tobacco smoking quit year: 1950.
- Chemical exposure type: Chemical Exposure, NOS; Occupation type: Textile, Fur and Leather Products Machine Operators.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Bladder Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CU-A0YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-CU-A0YR-01A-01-TS1: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 73; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CU-A0YR-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 3; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CU-A0YR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CU-A0YR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-CU-A0YR-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-CU-A0YR-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation primary: Textile Industry Factory Worker; Occupation primary chemical exposure: Yes; Occupation primary industry: Textiles; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Anterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT3b.
- Stage record, Gleason grading: Gleason score: 8.
- Metastatic site list: Metastasis site: Lymph node only.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; New tumor event type: Metastatic; New tumor event site: Lymph Node Only; New tumor event surgery: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Cystoprostatectomy.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient was previously diagnosed with prostate cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 460 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 460 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 219 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CU-A0YR-01A-12D-A10T-01): tumor purity 0.47, ploidy 3.3, whole-genome doublings 1.
